Somatic mutation profile of tumor specimen TCGA-GD-A3OP-01A (aliquot TCGA-GD-A3OP-01A-21D-A21Z-08) from TCGA case TCGA-GD-A3OP, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 84.8 years (30,956 days).
Specimen TCGA-GD-A3OP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9898be6-3c0f-47b0-8966-87d811ae63c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GD-A3OP-10A (Blood Derived Normal), aliquot TCGA-GD-A3OP-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/efba0e72-f04a-4c23-9229-49899f031789

The open-access MAF lists 351 somatic variants for this specimen: 251 protein-altering or splice-affecting, 95 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 213, Silent 95, Nonsense Mutation 24, Splice Site 5, Splice Region 5, Intron 4, Frame Shift Del 2, In Frame Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC1 | c.3803C>T p.S1268L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs1261184337, COSV60693294; called by muse, mutect2, varscan2
- ABCG1 | c.324C>G p.F108L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.972); catalogued as COSV59209874; called by muse, mutect2
- ADAMTS2 | c.3440C>A p.S1147Y | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV52391331; called by muse, mutect2
- ADSL | c.669C>G p.D223E | Missense Mutation (SNP) | VAF 17/275 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.377); catalogued as COSV53410255; called by muse, mutect2
- AL031777.2 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV61912045, COSV61912079; called by muse, mutect2, varscan2
- ALG13 | c.2118G>A p.M706I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV52644434; called by muse, mutect2
- AMBN | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.092); catalogued as COSV59827971; called by muse, mutect2
- APCDD1L | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.15); catalogued as COSV64487812; called by muse, mutect2, varscan2
- ARHGEF12 | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.531); catalogued as COSV63107115; called by muse, mutect2
- ARPP21 | c.271C>A p.H91N | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV51798052, COSV51807275; called by muse, mutect2, varscan2
- ARSB | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53728606, COSV53730062; called by muse, mutect2, varscan2
- ARSI | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 9/105 reads (9%) | catalogued as rs189890558; called by muse, mutect2, varscan2
- ASGR2 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.97); PolyPhen benign (0.031); catalogued as rs1293336444, COSV54691433; called by muse, mutect2
- ATAD5 | c.4441-2A>T p.X1481_splice | Splice Site (SNP) | VAF 72/380 reads (19%) | catalogued as COSV58978454; called by muse, mutect2, varscan2
- ATL2 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV60055968; called by muse, mutect2, varscan2
- ATRN | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV53533419; called by muse, mutect2, varscan2
- ATRNL1 | c.2162G>T p.S721I | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV61815708; called by muse, mutect2, varscan2
- ATRX | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 26/530 reads (5%) | catalogued as COSV100971174; called by muse, mutect2
- BIRC6 | c.4394G>A p.G1465E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.03); catalogued as COSV70205055; called by muse, mutect2, varscan2
- BIRC6 | c.4510G>A p.D1504N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101428585, COSV70205060; called by muse, mutect2, varscan2
- BLM | c.2936G>C p.R979T | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61927085; called by muse, mutect2
- BLZF1 | c.798-1G>A p.X266_splice | Splice Site (SNP) | VAF 22/340 reads (6%) | catalogued as COSV61394778; called by muse, mutect2
- BMS1 | c.2110G>C p.E704Q | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.113); catalogued as COSV65735349; called by muse, mutect2
- BNIPL | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV54848721; called by muse, mutect2
- BOD1L1 | c.8803G>A p.D2935N | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs952879898; called by muse, mutect2
- BPNT1 | c.406C>G p.L136V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59041305; called by muse, mutect2
- BRAF | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 17/173 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV56360210; called by muse, mutect2
- BTK | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as CM030798, COSV58117498; called by muse, mutect2
- C19orf12 | c.179C>T p.P60L (on ENST00000392278 / NM_001031726.3; = p.P49L on NM_031448.6) | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as rs1424999393, CM132611, COSV60365637; called by muse, mutect2, varscan2
- C1orf189 | c.118G>A p.G40S | Missense Mutation (SNP) | VAF 19/557 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63891271; called by muse, mutect2
- C1orf54 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.907); catalogued as COSV64859371; called by muse, mutect2, varscan2
- C2orf16 | c.5914C>T p.P1972S | Missense Mutation (SNP) | VAF 28/276 reads (10%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.042); catalogued as COSV62678060; called by muse, mutect2
- CALCR | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs940288459, COSV64011484; called by muse, mutect2
- CAP1 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 13/255 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61224409; called by muse, mutect2
- CARS2 | c.1334G>A p.R445K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV57288852; called by muse, mutect2
- CC2D1A | c.749-1G>A p.X250_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | catalogued as COSV58786027; called by muse, mutect2, varscan2
- CC2D2A | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs772016081, COSV67504953; ClinVar: uncertain significance; called by muse, mutect2
- CCT6B | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV58491685; called by muse, mutect2
- CD180 | c.1101G>C p.E367D | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV56519602; called by muse, mutect2, varscan2
- CD300LB | c.561C>G p.I187M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.473); catalogued as COSV58726365; called by muse, mutect2
- CDC42BPA | c.2611T>C p.F871L | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62019520; called by muse, mutect2
- CENPS-CORT | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV58364046; called by muse, mutect2
- CHD7 | c.3041G>A p.G1014E | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV71114189; called by muse, mutect2
- CHD7 | c.4072G>A p.D1358N | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV71114193; called by muse, mutect2, varscan2
- CLASRP | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 11/143 reads (8%) | SIFT deleterious (0.02); catalogued as COSV55515833, COSV55518960; called by muse, mutect2
- CLDND1 | c.620A>G p.N207S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as rs750569803, COSV57859882; called by muse, mutect2, varscan2
- CLEC16A | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as COSV68501713; called by muse, mutect2, varscan2
- CLSTN3 | c.1223C>G p.S408C | Missense Mutation (SNP) | VAF 19/158 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749011347, COSV56939960; called by muse, mutect2
- COMMD9 | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54673242; called by muse, mutect2
- CRLF1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.209); catalogued as COSV66505501; called by muse, varscan2
- CSE1L | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as COSV53704877; called by muse, mutect2
- CTPS2 | c.723C>T p.V241= | Splice Region (SNP) | VAF 10/177 reads (6%) | catalogued as COSV63724033; called by muse, mutect2
- CTTNBP2 | c.1672C>T p.P558S | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.754); catalogued as COSV50466431; called by muse, mutect2
- CUL7 | c.3120G>C p.K1040N | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54821529; called by muse, mutect2
- DCAF12L2 | c.647C>A p.T216N | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63584037, COSV63584108; called by muse, mutect2, varscan2
- DCAF4L1 | c.303C>G p.I101M | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100295914, COSV60788497; called by muse, mutect2
- DCDC1 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV60857056; called by muse, mutect2, varscan2
- DKKL1 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.457); catalogued as COSV55563730; called by muse, mutect2
- DLEC1 | c.5257C>G p.H1753D | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.124); catalogued as COSV57179725; called by muse, mutect2
- DNAH17 | c.2266A>G p.T756A | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.522); catalogued as COSV67760540; called by muse, mutect2
- DNAH2 | c.1429T>C p.S477P | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as COSV50019817; called by muse, mutect2
- DNAH6 | c.2147C>A p.A716E | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV52880892; called by muse, mutect2, varscan2
- DOCK2 | c.4536G>T p.M1512I | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV56984735; called by muse, mutect2
- DOLPP1 | c.23C>G p.S8W | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.764); catalogued as COSV59910089; called by muse, varscan2
- EEA1 | c.1182G>C p.E394D | Missense Mutation (SNP) | VAF 12/291 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV59289568; called by muse, mutect2
- EFNB2 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV55367299; called by muse, mutect2
- EIF2AK1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52238311; called by muse, mutect2, varscan2
- ELF3 | c.45del p.F15Lfs*28 | Frame Shift Del (DEL) | VAF 41/271 reads (15%) | catalogued as COSV62838238, COSV62840231; called by mutect2, pindel, varscan2
- EPN2 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV59063343; called by muse, mutect2
- ESRP1 | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV64412443; called by muse, mutect2
- EXOC3L4 | c.1927G>T p.D643Y | Missense Mutation (SNP) | VAF 24/459 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs970894365, COSV66295940; called by muse, mutect2
- FAM111B | c.1553C>G p.T518S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.039); catalogued as rs771169485, COSV59113507; called by muse, mutect2
- FAM126B | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); catalogued as COSV53774972; called by muse, mutect2, varscan2
- FAM234A | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV56997884; called by muse, mutect2, varscan2
- FCSK | c.482C>T p.P161L | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV55374948; called by muse, mutect2, varscan2
- FGD6 | c.2495C>T p.S832F | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV59693890, COSV59696758; called by muse, mutect2
- FLG | c.5225C>A p.P1742H | Missense Mutation (SNP) | VAF 62/632 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.028); catalogued as COSV64248108; called by muse, mutect2
- FLNA | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1569551872, COSV61041804; called by muse, mutect2, varscan2
- FMC1-LUC7L2 | c.106C>G p.R36G | Missense Mutation (SNP) | VAF 8/109 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.1); catalogued as COSV52546314; called by muse, mutect2
- FMN2 | c.2750G>A p.G917E | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.378); catalogued as COSV60419258, COSV60445924; called by muse, mutect2
- GAK | c.3511C>T p.Q1171* | Nonsense Mutation (SNP) | VAF 5/78 reads (6%) | catalogued as COSV100034112; called by muse, mutect2
- GALNT17 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV61155570, COSV61162889; called by muse, mutect2
- GALNT17 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV61188042; called by muse, mutect2
- GBE1 | c.1761G>A p.M587I | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.162); catalogued as COSV70102326; called by muse, mutect2
- GBP5 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV58594202; called by muse, mutect2, varscan2
- GC | c.149G>C p.R50T | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56739654, COSV99909919; called by muse, mutect2
- GNRH1 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52382628; called by muse, mutect2
- HCFC1 | c.1608G>T p.V536= | Splice Region (SNP) | VAF 4/28 reads (14%) | catalogued as COSV60077144; called by muse, mutect2, varscan2
- HCN1 | c.1522G>A p.V508M | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as rs180790607, COSV57495369, COSV57501466; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HERC2 | c.10594C>T p.Q3532* | Nonsense Mutation (SNP) | VAF 8/142 reads (6%) | catalogued as COSV99876571; called by muse, mutect2
- HSPA1A | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV65149460; called by muse, mutect2
- HTR4 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58803676; called by muse, mutect2
- HTT | c.6668G>A p.R2223Q | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as rs375059996; called by muse, mutect2
- IGLV2-11 | c.332C>G p.S111* | Nonsense Mutation (SNP) | VAF 21/236 reads (9%) | catalogued as rs747047277; called by muse, mutect2
- INTS12 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV60863501; called by muse, mutect2
- INTS3 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.503); catalogued as COSV59681250; called by muse, mutect2
- ITIH6 | c.2285C>T p.P762L | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.514); catalogued as rs1257412704, COSV54494036; called by muse, mutect2
- IZUMO2 | c.231G>T p.V77= | Splice Region (SNP) | VAF 9/96 reads (9%) | catalogued as COSV53231353; called by muse, mutect2
- KCND2 | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 9/102 reads (9%) | catalogued as COSV58574269; called by muse, mutect2
- KCNK6 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553235571, COSV54580065; called by muse, mutect2, varscan2
- KCNN3 | c.1732C>T p.Q578* (on ENST00000618040 / NM_001204087.1; = p.Q563* on NM_002249.6) | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV55215220; called by muse, mutect2, varscan2
- KCNQ1 | c.1348G>C p.E450Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs148266527, COSV50127492; called by mutect2, varscan2
- KDR | c.3062C>T p.S1021L | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55774920; called by muse, mutect2, varscan2
- KIF1B | c.1963G>A p.E655K (on ENST00000377086 / NM_001365952.1; = p.E609K on NM_015074.3) | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV55815377; called by muse, mutect2, varscan2
- KIF7 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 18/238 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV67999301; called by muse, mutect2
- KIRREL1 | c.1588G>C p.D530H | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV63290955; called by muse, mutect2
- KMT2D | c.2114C>A p.S705* | Nonsense Mutation (SNP) | VAF 13/138 reads (9%) | catalogued as COSV56418205, COSV99984157; called by muse, mutect2
- KMT2D | c.1709C>G p.S570C | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV56482226; called by muse, mutect2
- KNSTRN | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.005); catalogued as COSV51110337; called by muse, mutect2
- KRT13 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 54/968 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.478); catalogued as rs202015813, COSV55840904, COSV55841784; called by muse, mutect2
- KRT17 | c.917C>G p.T306S | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.122); catalogued as COSV60861883; called by muse, mutect2, varscan2
- LGR5 | c.1070+1G>A p.X357_splice | Splice Site (SNP) | VAF 7/121 reads (6%) | catalogued as COSV57009438; called by muse, mutect2
- LPAR4 | c.428C>G p.P143R | Missense Mutation (SNP) | VAF 6/144 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70912676, COSV70913335, COSV70913586; called by muse, mutect2
- LRP12 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.982); catalogued as COSV52634099; called by muse, mutect2
- LRRC41 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.173); catalogued as rs1481447513, COSV58442238; called by muse, mutect2, varscan2
- LRRK2 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.162); catalogued as COSV54168916; called by muse, mutect2, varscan2
- LZTS1 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as rs779973869, COSV56117255; called by mutect2, varscan2
- MACO1 | c.1919A>G p.Y640C | Missense Mutation (SNP) | VAF 21/216 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.983); catalogued as rs1275368078, COSV65478183; called by muse, mutect2
- MAP2 | c.3775G>A p.D1259N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.81); catalogued as COSV52306272; called by muse, mutect2, varscan2
- MAPRE3 | c.708C>G p.I236M | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.685); catalogued as COSV51869160; called by muse, mutect2, varscan2
- MCM10 | c.1055G>A p.G352E (on ENST00000484800 / NM_182751.3; = p.G351E on NM_018518.5) | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66336573; called by muse, mutect2, varscan2
- MED13 | c.5955C>G p.F1985L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV67266725; called by muse, mutect2, varscan2
- MEOX2 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV56294165; called by muse, mutect2, varscan2
- MEPE | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV63074383; called by muse, mutect2, varscan2
- MFGE8 | c.919G>T p.A307S | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV51557690; called by muse, mutect2, varscan2
- MILR1 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101660241; called by muse, mutect2, varscan2
- MIPOL1 | c.1122G>C p.E374D | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.083); catalogued as COSV59392591; called by muse, mutect2
- MUC5AC | c.151G>A p.G51R | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); catalogued as COSV62255358; called by muse, mutect2, varscan2
- MUC5B | c.5715G>C p.W1905C | Missense Mutation (SNP) | VAF 22/290 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV71595128; called by muse, mutect2
- MYH4 | c.348C>T p.Y116= | Splice Region (SNP) | VAF 14/133 reads (11%) | catalogued as rs750137859, COSV55118524; called by muse, mutect2
- NBN | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.804); catalogued as rs1554566610; ClinVar: uncertain significance; called by muse, mutect2
- NCAM1 | c.2041G>A p.E681K (on ENST00000316851 / NM_181351.5; = p.E671K on NM_000615.7) | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100377999, COSV57523945; called by muse, mutect2
- NEK9 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as COSV53133398; called by muse, mutect2
- NEUROD1 | c.554C>T p.A185V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375030401; called by muse, mutect2
- NLRC4 | c.1158C>G p.F386L | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61594528; called by muse, mutect2, varscan2
- NMRAL1 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52059195, COSV52060886; called by muse, mutect2
- NOG | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60446910; called by muse, mutect2
- NPY5R | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 20/398 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as rs1253366451, COSV58453749; called by muse, mutect2
- NRXN1 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as COSV58460381, COSV58500607; called by muse, mutect2, varscan2
- NTRK1 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757590743, COSV62328358; called by muse, mutect2
- NUP210 | c.2110C>A p.Q704K | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV54413144; called by muse, mutect2, varscan2
- NUP35 | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV54559222; called by muse, mutect2
- OR13G1 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62945226; called by muse, mutect2, varscan2
- OR1D2 | c.826A>T p.M276L | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV58922371; called by muse, mutect2
- OR56A4 | c.400C>G p.P134A | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58110073; called by muse, mutect2, varscan2
- OR6F1 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.057); catalogued as COSV57469304; called by muse, mutect2
- OR7C1 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 8/213 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.49); catalogued as COSV50183694; called by muse, mutect2
- PADI2 | c.985G>C p.E329Q | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.414); catalogued as COSV64946588; called by muse, mutect2
- PAPOLA | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV53485009; called by muse, mutect2
- PCDHB9 | c.409G>C p.E137Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.829); catalogued as rs782272485, COSV53378001; called by muse, mutect2
- PIGU | c.510C>G p.F170L | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.744); catalogued as COSV54166040; called by muse, mutect2
- PIK3CA | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV55988096, COSV99838734; called by muse, mutect2, varscan2
- PKHD1L1 | c.8683C>T p.H2895Y | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.326); catalogued as COSV65751778; called by muse, mutect2, varscan2
- PLGRKT | c.429C>G p.F143L | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV56352393, COSV56352779; called by muse, mutect2
- POT1 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV62934256; called by muse, mutect2, varscan2
- PRKCG | c.2040C>A p.F680L | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV54732320, COSV54733289; called by muse, mutect2
- PRMT8 | c.937A>G p.I313V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV54218616; called by muse, mutect2
- PSG8 | c.801G>T p.E267D | Missense Mutation (SNP) | VAF 24/484 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV60610679, COSV60615463; called by muse, mutect2
- PSMC6 | c.938T>G p.I313R (on ENST00000612399; = p.I299R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV71629232; called by muse, mutect2
- QARS1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141072684; called by muse, mutect2, varscan2
- RAB11FIP4 | c.1787C>T p.S596L | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs778767376, COSV57930340; called by muse, mutect2
- RASAL2 | c.1690G>C p.D564H | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as COSV62722108; called by muse, mutect2
- RNF207 | c.922G>C p.E308Q | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV65008350; called by muse, mutect2
- RTN1 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV50720846, COSV50745198; called by muse, mutect2
- SACS | c.12562G>A p.A4188T | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV66546335; called by muse, mutect2
- SAT2 | c.153C>G p.F51L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV52647812; called by muse, mutect2
- SBF2 | c.3688G>A p.E1230K | Missense Mutation (SNP) | VAF 7/131 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV56310095; called by muse, mutect2
- SCUBE1 | c.1238C>T p.T413I | Missense Mutation (SNP) | VAF 21/306 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62615915; called by muse, mutect2
- SEH1L | c.838C>T p.Q280* | Nonsense Mutation (SNP) | VAF 17/236 reads (7%) | catalogued as COSV100040203; called by muse, mutect2
- SERPINA11 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1243656394, COSV58243101; called by muse, mutect2
- SERTAD2 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs184187916; called by muse, mutect2, varscan2
- SLC22A2 | c.1280-1G>C p.X427_splice | Splice Site (SNP) | VAF 9/81 reads (11%) | catalogued as COSV65267831; called by muse, mutect2, varscan2
- SLC26A7 | c.1367G>C p.G456A | Missense Mutation (SNP) | VAF 38/447 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781445117, COSV52603707; called by muse, mutect2
- SLCO1B3 | c.1570T>A p.C524S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53945291; called by muse, mutect2
- SLCO2A1 | c.1514G>A p.G505E | Missense Mutation (SNP) | VAF 29/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60489005; called by muse, mutect2, varscan2
- SLCO2B1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs998397411, COSV56939066; called by muse, mutect2
- SMAD6 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56597150; called by muse, mutect2, varscan2
- SMC2 | c.3046C>T p.L1016F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV53964434; called by muse, mutect2
- SMO | c.838G>T p.G280C | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50841555; called by muse, mutect2, varscan2
- SNAP23 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51042115; called by muse, mutect2
- SPAG9 | c.3869C>T p.S1290L (on ENST00000262013 / NM_001130528.3; = p.S1276L on NM_003971.6) | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV56243025; called by muse, mutect2
- SPATA5 | c.2116G>C p.E706Q | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56783489; called by muse, mutect2
- SRC | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62441060; called by muse, mutect2
- SRCAP | c.4573C>G p.L1525V | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.609); catalogued as rs749522651, COSV52680066; called by mutect2, varscan2
- STAU1 | c.1493G>A p.R498K (on ENST00000371856 / NM_001319135.1; = p.R417K on NM_004602.3) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61462314; called by muse, mutect2, varscan2
- SV2B | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs201612018, COSV57701832; called by mutect2, varscan2
- TAS2R30 | c.495G>T p.K165N | Missense Mutation (SNP) | VAF 12/183 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as rs758242189, COSV67862170; called by muse, mutect2
- TBX15 | c.1607G>A p.S536N (on ENST00000369429 / NM_001330677.2; = p.S430N on NM_152380.3) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.021); catalogued as COSV52875658; called by muse, mutect2
- TEC | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV67406266; called by muse, mutect2
- TENM3 | c.3836T>C p.V1279A | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV69317935; called by muse, mutect2, varscan2
- TKTL2 | c.1538G>A p.G513E | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560903719, COSV54921043; called by muse, mutect2, varscan2
- TMEM151A | c.1396G>A p.G466S | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs1272100358, COSV59175097; called by muse, mutect2, varscan2
- TMOD4 | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.315); catalogued as COSV54861886; called by muse, mutect2
- TNFAIP8 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as COSV57229164; called by muse, mutect2
- TOM1L2 | c.1289C>T p.A430V (on ENST00000379504 / NM_001350333.2; = p.A380V on NM_001033551.3) | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1209314216, COSV58888088; called by muse, mutect2, varscan2
- TRANK1 | c.4313G>T p.R1438L | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as COSV57162794; called by muse, mutect2, varscan2
- TRIM2 | c.1610C>T p.T537I (on ENST00000437508; = p.T564I on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58638231; called by muse, mutect2
- TRIM49 | c.1225G>A p.V409I | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.665); catalogued as rs781188443, COSV100316165; called by muse, mutect2, varscan2
- TRIO | c.4504C>T p.R1502* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | catalogued as COSV60078639; called by muse, mutect2
- TRIP4 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 6/107 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV56033217; called by muse, mutect2
- TRMT10C | c.317G>C p.R106T | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV59306778; called by muse, mutect2
- TSPAN18 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 26/359 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0.395); catalogued as rs754511785, COSV60885412; called by muse, mutect2
- TTN | c.38491G>C p.E12831Q (on ENST00000591111; = p.E5407Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/138 reads (10%) | PolyPhen possibly damaging (0.836); catalogued as COSV60310944; called by muse, mutect2, varscan2
- UACA | c.3231G>C p.Q1077H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV100537559, COSV59859481; called by muse, mutect2, varscan2
- UBXN2A | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.021); catalogued as COSV58337777; called by muse, mutect2
- UIMC1 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.297); catalogued as rs1482715401, COSV65895029; called by muse, mutect2
- UPF2 | c.2980G>A p.E994K | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1341954950, COSV62663525; called by muse, mutect2
- UPF3B | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 11/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52230451; called by muse, mutect2
- USP2 | c.77G>A p.G26D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.356); catalogued as COSV52731793; called by muse, mutect2, varscan2
- VDAC2 | c.637C>T p.L213F | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV53685146, COSV53686444; called by muse, mutect2
- VILL | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as rs1253523138, COSV52187710; called by muse, mutect2, varscan2
- VIP | c.105C>T p.L35= | Splice Region (SNP) | VAF 6/50 reads (12%) | catalogued as COSV65889584, COSV65889715; called by mutect2, varscan2
- VSIG4 | c.83G>C p.S28T | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV66074865; called by muse, mutect2
- WDHD1 | c.2402C>G p.S801C | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); catalogued as COSV62215485; called by muse, mutect2
- XKRX | c.891T>A p.N297K | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV60709203; called by muse, mutect2
- XPO4 | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as COSV55012508; called by muse, mutect2
- ZBTB11 | c.2284G>A p.E762K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as COSV57246838; called by muse, mutect2
- ZBTB7B | c.364C>T p.L122F (on ENST00000292176; = p.L156F on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52694650; called by muse, mutect2
- ZFP30 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.051); catalogued as COSV63623077; called by muse, mutect2, varscan2
- ZNF407 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1165757173, COSV55268289; called by muse, mutect2, varscan2
- ZNF407 | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV55268324; called by muse, mutect2
- ZNF407 | c.2682G>T p.M894I | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs757075811, COSV55268358; called by muse, mutect2, varscan2
- ZXDC | c.2504C>T p.S835L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV61504424; called by muse, mutect2, varscan2
- AGO2 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- AHR | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- ALAS1 | c.527_532del p.K176_Q177del | In Frame Del (DEL) | VAF 20/140 reads (14%) | called by mutect2, pindel
- BIRC6 | c.4252G>T p.D1418Y | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- CCDC121 | c.642G>C p.Q214H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- CCDC83 | c.1069_1071del p.K357del (on ENST00000342404 / NM_001286159.2; = p.K388del on NM_173556.5) | In Frame Del (DEL) | VAF 13/118 reads (11%) | called by mutect2, pindel, varscan2
- CCR7 | c.204_205del p.I68Mfs*85 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- CHD1 | c.3457C>T p.R1153* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | called by muse, mutect2, varscan2
- CUL4B | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 14/143 reads (10%) | called by muse, mutect2
- DVL2 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.017); called by muse, mutect2
- DZIP1 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- FASTK | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HADH | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.025); called by muse, mutect2
- IFT81 | c.1579G>C p.E527Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- KRT72 | c.1064C>G p.S355* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.1408G>C p.D470H (on ENST00000418998 / NM_001377303.1; = p.D380H on NM_015478.7) | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LARP4 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2
- MED13 | c.3602C>A p.S1201* | Nonsense Mutation (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
- MED23 | c.1976C>A p.S659* | Nonsense Mutation (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- NCOA6 | c.490G>T p.G164* | Nonsense Mutation (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2, varscan2
- PLA2G3 | c.988C>T p.Q330* | Nonsense Mutation (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- RAC1 | c.157C>G p.L53V | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- TMC8 | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- TMEM169 | c.839C>G p.S280* | Nonsense Mutation (SNP) | VAF 8/109 reads (7%) | called by muse, mutect2
- TNK2 | c.835C>T p.Q279* | Nonsense Mutation (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- ZFP69B | c.481G>C p.D161H | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.436); called by muse, mutect2
- ZNF407 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.001); called by muse, mutect2
- ZRSR2 | c.128C>G p.S43* | Nonsense Mutation (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- ABCB6 | c.1791C>T p.F597= | Silent (SNP) | VAF 7/65 reads (11%) | catalogued as COSV54692425; called by muse, mutect2, varscan2
- ABHD3 | c.717G>A p.L239= | Silent (SNP) | VAF 7/143 reads (5%) | catalogued as COSV56678214; called by muse, mutect2
- ABL1 | c.2295G>A p.K765= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV59340040; called by muse, mutect2
- AKAP8L | c.1323G>A p.K441= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1250838465, COSV68474529; called by muse, mutect2, varscan2
- AKR1A1 | c.19C>T p.L7= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as COSV61087633; called by muse, mutect2
- APBB1IP | c.576G>A p.L192= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as rs1258978472, COSV63076663; called by muse, mutect2
- ATF7 | c.36G>T p.P12= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV60646114; called by mutect2, varscan2
- ATOH7 | c.168C>G p.L56= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- ATP1A3 | c.468G>A p.K156= (on ENST00000545399 / NM_001256214.2; = p.K143= on NM_152296.5) | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as COSV57490929; called by muse, mutect2
- ATP2B3 | c.2286G>A p.L762= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- ATRN | c.2712G>A p.L904= | Silent (SNP) | VAF 10/251 reads (4%) | catalogued as COSV53533433; called by muse, mutect2
- C2orf68 | c.453C>G p.L151= | Silent (SNP) | VAF 10/143 reads (7%) | catalogued as COSV60472697; called by muse, mutect2
- C4orf50 | c.633C>T p.V211= (on ENST00000324058; = p.V1443= on NM_001364689.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV60690429; called by muse, mutect2
- CACNA1S | c.531G>A p.S177= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs750087191, COSV62939004; called by muse, mutect2, varscan2
- CAPN2 | c.1938C>T p.I646= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as rs374729587; called by muse, mutect2
- CNTN3 | c.285A>G p.T95= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as rs1478782683, COSV55182967; called by muse, mutect2
- CRACDL | c.2469G>A p.A823= | Silent (SNP) | VAF 16/133 reads (12%) | catalogued as rs765707391, COSV67407176; called by muse, mutect2, varscan2
- CRYBB3 | c.312C>G p.L104= | Silent (SNP) | VAF 36/362 reads (10%) | catalogued as COSV53194736; called by muse, mutect2
- DENND1B | c.216A>C p.V72= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV52471776; called by muse, mutect2, varscan2
- DNAH2 | c.4368C>T p.I1456= | Silent (SNP) | VAF 27/216 reads (13%) | catalogued as COSV66726228; called by muse, mutect2, varscan2
- DNAH6 | c.2148A>G p.A716= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV52880925; called by muse, mutect2, varscan2
- FAM234A | c.939C>T p.L313= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100056434, COSV56997905; called by muse, mutect2, varscan2
- FASTKD5 | c.1482C>G p.L494= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV53911159; called by muse, mutect2
- GDI2 | c.1149C>T p.I383= | Silent (SNP) | VAF 6/126 reads (5%) | catalogued as COSV60169428; called by muse, mutect2
- GEMIN8 | c.685C>A p.R229= | Silent (SNP) | VAF 12/182 reads (7%) | catalogued as COSV60551395; called by muse, mutect2
- H2AC11 | c.252C>A p.L84= | Silent (SNP) | VAF 23/205 reads (11%) | catalogued as COSV60362702; called by muse, mutect2, varscan2
- HLA-G | c.1002G>A p.K334= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs766696298, COSV64406775; called by muse, mutect2, varscan2
- HMCN1 | c.12591A>G p.T4197= | Silent (SNP) | VAF 12/142 reads (8%) | catalogued as COSV54899831, COSV54936877; called by muse, mutect2
- HRH1 | c.445C>T p.L149= | Silent (SNP) | VAF 6/115 reads (5%) | catalogued as COSV67955701, COSV67955944; called by muse, mutect2
- IGKV3D-7 | c.54C>A p.L18= | Silent (SNP) | VAF 24/215 reads (11%) | called by muse, mutect2, varscan2
- JUP | c.1458G>A p.V486= | Silent (SNP) | VAF 7/151 reads (5%) | catalogued as COSV60279571; called by muse, mutect2
- KANSL2 | c.1188G>A p.E396= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV63480388; called by muse, mutect2, varscan2
- KIAA0232 | c.291G>A p.K97= | Silent (SNP) | VAF 12/132 reads (9%) | catalogued as COSV56925861, COSV56928926; called by muse, mutect2
- KIAA1210 | c.210A>G p.A70= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV68179841; called by muse, mutect2, varscan2
- KTN1 | c.2805G>A p.L935= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV63215793; called by muse, mutect2, varscan2
- L3MBTL1 | c.1638G>A p.E546= (on ENST00000418998 / NM_001377303.1; = p.E456= on NM_015478.7) | Silent (SNP) | VAF 9/148 reads (6%) | catalogued as COSV64229574; called by muse, mutect2
- LCP1 | c.1575G>A p.V525= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs111548644; called by muse, mutect2, varscan2
- LPAR4 | c.225T>A p.A75= | Silent (SNP) | VAF 10/245 reads (4%) | catalogued as COSV70912361, COSV70913328; called by muse, mutect2
- LRRC7 | c.2364T>C p.N788= (on ENST00000651989 / NM_001370785.2; = p.N755= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 42/261 reads (16%) | catalogued as COSV50610146; called by muse, mutect2, varscan2
- LTBP3 | c.1578G>A p.Q526= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV57243779; called by muse, mutect2
- MAGI3 | c.711T>G p.P237= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV56843492; called by muse, mutect2, varscan2
- MAPK3 | c.111C>T p.D37= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as rs980128823, COSV53776350; called by muse, mutect2
- MBNL2 | c.645A>G p.V215= | Silent (SNP) | VAF 16/147 reads (11%) | catalogued as COSV59125208; called by muse, mutect2, varscan2
- MCCC1 | c.921C>T p.V307= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as COSV55611536; called by muse, mutect2
- MCM10 | c.1056G>A p.G352= (on ENST00000484800 / NM_182751.3; = p.G351= on NM_018518.5) | Silent (SNP) | VAF 16/157 reads (10%) | catalogued as COSV66336586; called by muse, varscan2
- MED13 | c.3498C>A p.L1166= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as COSV67262435, COSV67262991, COSV67266731; called by muse, mutect2
- MFN1 | c.456G>A p.L152= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV54942266; called by muse, mutect2
- MYLK4 | c.672C>G p.L224= | Silent (SNP) | VAF 27/177 reads (15%) | catalogued as COSV51150550; called by muse, mutect2, varscan2
- MYO1G | c.147G>A p.V49= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV51856795; called by muse, mutect2, varscan2
- NAIP | c.498C>T p.F166= | Silent (SNP) | VAF 5/94 reads (5%) | catalogued as COSV52002672; called by muse, mutect2
- NID1 | c.2178C>T p.I726= | Silent (SNP) | VAF 13/292 reads (4%) | catalogued as COSV51628171; called by muse, mutect2
- NMRAL1 | c.828G>A p.L276= | Silent (SNP) | VAF 14/319 reads (4%) | catalogued as rs1366639725, COSV52061116; called by muse, mutect2
- NPHP3 | c.1932G>A p.V644= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV58628917, COSV58633165; called by muse, mutect2
- NTRK2 | c.618C>T p.L206= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as COSV52880121; called by muse, mutect2
- OR2G6 | c.861C>T p.P287= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV58575710; called by muse, mutect2, varscan2
- OR2W3 | c.876C>A p.L292= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV100831759; called by muse, mutect2
- OR5H2 | c.606A>G p.L202= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV62351779; called by muse, mutect2, varscan2
- OR5T3 | c.703T>C p.L235= | Silent (SNP) | VAF 18/250 reads (7%) | catalogued as rs1358043593, COSV57382400; called by muse, mutect2
- OR6K3 | c.546G>T p.L182= (on ENST00000368146; = p.L166= on NM_001005327.2) | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as COSV63746408; called by muse, mutect2
- OR6Q1 | c.762C>T p.L254= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV56932793, COSV56933155, COSV56934105; called by muse, mutect2, varscan2
- OR7A17 | c.165C>G p.L55= | Silent (SNP) | VAF 7/109 reads (6%) | catalogued as COSV59414307; called by muse, mutect2
- PARP4 | c.4413G>A p.L1471= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as COSV67963976; called by muse, mutect2, varscan2
- PCDHB7 | c.576C>G p.P192= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV50781338, COSV50809909; called by muse, mutect2
- PCDHB7 | c.963C>T p.A321= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV50767316, COSV50810019; called by muse, mutect2
- PIP4K2A | c.1014C>G p.V338= | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV60542489; called by muse, mutect2
- PKHD1L1 | c.9516C>G p.L3172= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV65751782; called by muse, mutect2, varscan2
- PLEKHO1 | c.1185C>G p.L395= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV50310916; called by muse, mutect2, varscan2
- PPFIA3 | c.2283G>A p.K761= | Silent (SNP) | VAF 9/214 reads (4%) | catalogued as COSV61954469; called by muse, mutect2
- PRAMEF19 | c.711C>G p.L237= | Silent (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- RCC1 | c.1080G>A p.V360= | Silent (SNP) | VAF 26/504 reads (5%) | catalogued as COSV65780107; called by muse, mutect2
- RNASET2 | c.372G>A p.Q124= | Silent (SNP) | VAF 13/153 reads (8%) | catalogued as COSV50352112; called by muse, mutect2
- RNF128 | c.399T>C p.H133= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV55254205; called by muse, mutect2
- SH3KBP1 | c.201C>T p.N67= | Silent (SNP) | VAF 19/184 reads (10%) | catalogued as COSV65644385; called by muse, mutect2, varscan2
- SH3PXD2B | c.2124C>T p.R708= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs370525113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC25A39 | c.1008C>T p.I336= (on ENST00000377095 / NM_001143780.3; = p.I328= on NM_016016.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as rs1343998108, COSV56589001; called by muse, mutect2, varscan2
- SLC35A5 | c.585C>T p.F195= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV53727960; called by muse, mutect2, varscan2
- SLC4A1AP | c.1692G>A p.L564= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1300221059, COSV58137541; called by muse, mutect2, varscan2
- SSX3 | c.126C>G p.V42= | Silent (SNP) | VAF 10/191 reads (5%) | catalogued as COSV53646144; called by muse, mutect2
- TEKT4 | c.246C>T p.R82= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV54628127; called by muse, mutect2, varscan2
- TFCP2 | c.858C>T p.V286= | Silent (SNP) | VAF 7/77 reads (9%) | catalogued as COSV56935745; called by muse, mutect2
- TIPARP | c.108G>A p.L36= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV55814569, COSV55815576; called by muse, mutect2
- TMEFF1 | c.714A>T p.T238= | Silent (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
- TOX4 | c.819G>A p.K273= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as rs1278345473, COSV52971089; called by muse, mutect2
- TRIM55 | c.243T>C p.C81= | Silent (SNP) | VAF 73/311 reads (23%) | catalogued as COSV52550262; called by muse, mutect2, varscan2
- TTN | c.42582C>T p.A14194= (on ENST00000591111; = p.A6770= on NM_003319.4) | Silent (SNP) | VAF 8/121 reads (7%) | catalogued as COSV60310906; called by muse, mutect2
- TTN | c.26631C>A p.S8877= (on ENST00000591111; = p.S7950= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/353 reads (8%) | catalogued as COSV60311003; called by muse, mutect2
- UBAP2L | c.2841G>A p.V947= | Silent (SNP) | VAF 10/278 reads (4%) | catalogued as COSV55180452; called by muse, mutect2
- UGDH | c.627C>G p.L209= | Silent (SNP) | VAF 12/164 reads (7%) | catalogued as COSV57099739; called by muse, mutect2
- UNKL | c.1659G>C p.L553= | Silent (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- WDR75 | c.1713G>A p.L571= | Silent (SNP) | VAF 11/185 reads (6%) | catalogued as COSV59106912; called by muse, mutect2
- ZBTB39 | c.60C>G p.L20= | Silent (SNP) | VAF 12/298 reads (4%) | catalogued as COSV55630750; called by muse, mutect2
- ZIC2 | c.1209G>A p.T403= | Silent (SNP) | VAF 18/180 reads (10%) | catalogued as rs1396349409, COSV66255490; called by muse, mutect2
- ZNF285 | c.1275G>A p.E425= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV58410970; called by muse, mutect2, varscan2
- ZNF347 | c.1782G>A p.E594= | Silent (SNP) | VAF 21/190 reads (11%) | catalogued as COSV100498293, COSV61970714; called by muse, mutect2, varscan2
- ZP4 | c.852C>T p.S284= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV63910845; called by muse, mutect2
- CARS1 | c.26-5687G>A | Intron (SNP) | VAF 5/35 reads (14%) | catalogued as COSV53460469; called by muse, mutect2, varscan2
- P4HTM | c.1074-22C>T | Intron (SNP) | VAF 6/134 reads (4%) | catalogued as rs1260345994, COSV59088942; called by muse, mutect2
- RPL17-C18orf32 | c.81+65G>A | Intron (SNP) | VAF 18/250 reads (7%) | catalogued as rs1181687920, COSV100271762; called by muse, mutect2
- RPP38 | chr10:15096480 C>G | 5'Flank (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- RPS8 | c.518-183C>T | Intron (SNP) | VAF 52/648 reads (8%) | catalogued as COSV100785483; called by muse, mutect2
